Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0L9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0L9-01A (Primary Tumor).

[page 1 of 2]
TSS Name/#:

Specimens Submitted:

- 1: SP: Uterus, cervix, rt. tubeovary, lt. tubeovary
- 2: SP: Anterior vaginal wall
- 3: SP: Left external iliac lymph nodes
- 4: SP: Left obturator lymph nodes
- 5: SP: Left common iliac lymph node
- 6: SP: Right external iliac lymph node
- 7: Right common iliac lymph node
- 8: SP: Right obturator lymph node
- 9: SP: Right para-aortic lymph node
- 10: SP: Left para-aortic lymph node
- 11: SP: Omentum

DIAGNOSIS:

- 1) UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES, HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, PAPILLARY SEROUS TYPE. THE TUMOR ARISES WITHIN AN ENDOMETRIAL POLYP. THE TUMOR INVADES THE ENDOMETRIAL POLYP, HOWEVER NO MYOMETRIAL INVASION IS IDENTIFIED. NO ENDOCERVICAL INVASION IS IDENTIFIED. NO VASCULAR INVASION IS IDENTIFIED. THE UNINVOLVED ENDOMETRIUM IS UNREMARKABLE. THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): LEIOMYOMA(S). ALL ADNEXAE ARE UNREMARKABLE. THE PARAMETRIAL SOFT TISSUE IS UNREMARKABLE.
- 2) ANTERIOR VAGINAL WALL, BIOPSY:
- BENIGN SQUAMOUS EPITHELIUM AND FIBROMUSCULAR TISSUE.
- 3) LYMPH NODES, LEFT EXTERNAL ILIAC, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 4) LYMPH NODES, LEFT OBTURATOR, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 5) LYMPH NODE, LEFT COMMON ILIAC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 6) LYMPH NODES, RIGHT EXTERNAL ILIAC, EXCISION:
- THREE BENIGN LYMPH NODES (0/3).

** Continued on next page **

ICD-0-3

adenocarcinoma, serous, NOS 8441/3
Site: Endometrium C54.1

lw
5/1/11

[page 2 of 2]
TSS Name/#:

Page 2 of 5

- 7) LYMPH NODES, RIGHT COMMON ILIAC, EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 8) LYMPH NODE, RIGHT OBTURATOR, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 9) LYMPH NODE, RIGHT PARA-AORTIC, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 10) LYMPH NODE, LEFT PARA-AORTIC, EXCISION:
- ONE BENIGN LYMPH NODE.
- 11) OMENTUM, RESECTION:
- BENIGN FIBROADIPOSE TISSUE. NEGATIVE FOR TUMOR.

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file b0c0d58e-dda4-4c0c-92cc-86736f1f75cc (TCGA-AP-A0L9.62E44C56-838D-4318-B8F7-80476A148C03.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).